Somatic mutation profile of tumor specimen TARGET-20-PASILA-09A (aliquot TARGET-20-PASILA-09A-01D) from TARGET case TARGET-20-PASILA, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 14.7 years (5,386 days).
Specimen TARGET-20-PASILA-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d16b9553-ff21-4ba5-b717-892fd7fac423.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PASILA-14A (Bone Marrow Normal), aliquot TARGET-20-PASILA-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/161bc5a1-63c9-4f9a-a4de-4ad2edac2d59

The open-access MAF lists 7 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 5, Silent 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLT3 | c.1775T>C p.V592A | Missense Mutation (SNP) | VAF 36/296 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.04); catalogued as rs1057520025, COSV54051432, COSV54058572, COSV54074139; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PHF6 | c.644G>C p.C215S (on ENST00000332070 / NM_032458.3; = p.C216S on NM_032335.3) | Missense Mutation (SNP) | VAF 36/156 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV59699867; called by muse, mutect2, varscan2
- RUNX1 | c.232C>T p.H78Y (on ENST00000344691 / NM_001001890.3; = p.H105Y on NM_001754.5) | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55891356; called by muse, mutect2, varscan2
- BCOR | c.3052-2_3052del p.X1018_splice | Splice Site (DEL) | VAF 60/78 reads (77%) | called by mutect2, pindel, varscan2
- CHD4 | c.4217G>A p.R1406H (on ENST00000357008 / NM_001363606.2; = p.R1419H on NM_001273.5) | Missense Mutation (SNP) | VAF 39/236 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CHD4 | c.2656T>G p.L886V (on ENST00000357008 / NM_001363606.2; = p.L899V on NM_001273.5) | Missense Mutation (SNP) | VAF 18/240 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- COL6A3 | c.2757G>A p.A919= | Silent (SNP) | VAF 56/322 reads (17%) | catalogued as rs115874872; called by muse, mutect2, varscan2
